Somatic mutation profile of cancer-model specimen HCM-CSHL-0074-C25-85A (3D Organoid; aliquot HCM-CSHL-0074-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0074-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 54.2 years (19,813 days).
Specimen HCM-CSHL-0074-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cec9b2c-9bd6-4c72-886e-23852276c335.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0074-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0074-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a86035c3-fcf3-482a-afe7-ea657f9bc3fa

The open-access MAF lists 54 somatic variants for this specimen: 32 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 18, RNA 4, Nonsense Mutation 3, Frame Shift Del 3, In Frame Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 166/168 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 201/202 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762340085; called by muse, mutect2, varscan2
- ARHGAP22 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 188/375 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV50992174; called by muse, mutect2, varscan2
- F12 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV53692390; called by muse, mutect2, varscan2
- FAM90A14P | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 125/1171 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs1280625387; called by muse, mutect2, varscan2
- GABRB3 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 197/405 reads (49%) | catalogued as rs942355738, COSV100159239, COSV54660326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LYRM1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1037242716; called by muse, mutect2, varscan2
- MAP3K2 | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 173/352 reads (49%) | catalogued as rs1172583326; called by muse, mutect2, varscan2
- MUC5AC | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 193/384 reads (50%) | SIFT tolerated (0.1); catalogued as rs577204654; called by muse, mutect2, varscan2
- OR2T2 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 112/901 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776150314; called by muse, mutect2, varscan2
- OTUD7A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1194383682, COSV61044236; called by muse, mutect2, varscan2
- PRKCQ | c.1445+1G>A p.X482_splice | Splice Site (SNP) | VAF 108/279 reads (39%) | catalogued as rs1190765193, COSV54111433; called by muse, mutect2, varscan2
- PRKDC | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377127342; called by muse, mutect2, varscan2
- RSPO4 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 221/488 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs752310739; called by muse, mutect2, varscan2
- SCLY | c.1282C>T p.R428C (on ENST00000651534; = p.R420C on NM_016510.7) | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550794143, COSV54540675; called by muse, mutect2, varscan2
- SMAD3 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 387/782 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV59284555; called by muse, mutect2, varscan2
- SOX21 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.081); catalogued as rs868549237; called by muse, mutect2
- UBR4 | c.13328G>A p.R4443H | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64384256; called by muse, mutect2, varscan2
- ABCD2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AVL9 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- CCDC191 | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2
- CHD4 | c.3666A>T p.G1222= (on ENST00000357008 / NM_001363606.2; = p.G1235= on NM_001273.5) | Splice Region (SNP) | VAF 259/261 reads (99%) | called by muse, mutect2, varscan2
- CPSF3 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 79/146 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- H2AC16 | c.321_329dup p.V108_P110dup | In Frame Ins (INS) | VAF 142/195 reads (73%) | called by mutect2, varscan2
- MMP1 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MSTO1 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 74/280 reads (26%) | called by muse, mutect2, varscan2
- NKTR | c.4032del p.T1345Hfs*130 | Frame Shift Del (DEL) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- PDGFRA | c.1454A>C p.E485A | Missense Mutation (SNP) | VAF 166/332 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TAF2 | c.3083del p.P1028Hfs*3 | Frame Shift Del (DEL) | VAF 155/628 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.58005_58009del p.S19335Rfs*11 (on ENST00000591111; = p.S11911Rfs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 45/95 reads (47%) | called by mutect2, pindel, varscan2
- WNK4 | c.3728T>C p.M1243T | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BAHCC1 | c.2982C>T p.C994= | Silent (SNP) | VAF 120/245 reads (49%) | catalogued as rs1475816654; called by muse, mutect2, varscan2
- CDYL2 | c.927C>T p.S309= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as rs148507807; called by muse, mutect2, varscan2
- CNTN4 | c.2112G>A p.A704= | Silent (SNP) | VAF 102/215 reads (47%) | catalogued as rs759314373; called by muse, mutect2, varscan2
- DAGLA | c.2931C>T p.A977= | Silent (SNP) | VAF 123/238 reads (52%) | catalogued as rs145101853, COSV57198205, COSV99944712; called by muse, mutect2, varscan2
- DMAP1 | c.1152C>T p.C384= | Silent (SNP) | VAF 106/248 reads (43%) | called by muse, mutect2, varscan2
- FBLN2 | c.2064C>T p.P688= | Silent (SNP) | VAF 243/494 reads (49%) | catalogued as COSV99852463; called by muse, mutect2, varscan2
- H2AW | c.345A>G p.V115= | Silent (SNP) | VAF 44/726 reads (6%) | catalogued as rs761793820, COSV64209514; called by muse, mutect2
- H2AW | c.318T>C p.G106= | Silent (SNP) | VAF 78/824 reads (9%) | catalogued as rs758423488, COSV64209520; called by muse, mutect2
- IGDCC4 | c.2217G>A p.P739= | Silent (SNP) | VAF 63/178 reads (35%) | catalogued as rs748792377; called by muse, mutect2, varscan2
- LHFPL3 | c.234C>T p.G78= | Silent (SNP) | VAF 14/426 reads (3%) | catalogued as COSV67804761; called by muse, mutect2
- MBTPS2 | c.252A>C p.V84= | Silent (SNP) | VAF 262/263 reads (100%) | called by muse, mutect2, varscan2
- PAOX | c.1446G>T p.T482= | Silent (SNP) | VAF 152/310 reads (49%) | catalogued as COSV53373689, COSV53375397; called by muse, mutect2, varscan2
- PRX | c.3645C>T p.T1215= | Silent (SNP) | VAF 149/345 reads (43%) | catalogued as rs777917125, COSV52523864; called by muse, mutect2, varscan2
- SMG6 | c.3456G>A p.K1152= | Silent (SNP) | VAF 7/196 reads (4%) | catalogued as rs970711004, COSV53962905; called by muse, mutect2
- STAB2 | c.2508C>T p.F836= | Silent (SNP) | VAF 109/209 reads (52%) | catalogued as COSV101185987; called by muse, mutect2, varscan2
- TTN | c.13350C>T p.C4450= (on ENST00000591111; = p.C4404= on NM_003319.4) | Silent (SNP) | VAF 76/159 reads (48%) | catalogued as rs1217230000, COSV60205177; called by muse, mutect2, varscan2
- VARS1 | c.1920G>A p.V640= | Silent (SNP) | VAF 201/204 reads (99%) | called by muse, mutect2, varscan2
- XKR6 | c.579G>A p.L193= | Silent (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- AC020910.3 | n.509C>T | RNA (SNP) | VAF 54/122 reads (44%) | catalogued as rs950833386; called by muse, mutect2, varscan2
- AC024940.1 | n.2417G>A | RNA (SNP) | VAF 84/711 reads (12%) | called by muse, mutect2, varscan2
- AC139795.1 | n.1536C>T | RNA (SNP) | VAF 161/350 reads (46%) | catalogued as rs774291394; called by muse, mutect2, varscan2
- UGT2B27P | n.1439T>C | RNA (SNP) | VAF 189/402 reads (47%) | catalogued as rs769540632; called by muse, mutect2, varscan2
